Surgical pathology report (de-identified scan), TCGA case TCGA-WS-AB45, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Kansas, specimen TCGA-WS-AB45-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

NAME: SURG PATH #:
MR #: SPECIMEN CLASS:
BILLING #: ALT ID #:
LOCATION: DATE OF PROCEDURE:
AGE: DATE RECEIVED:
SEX: F TIME RECEIVED:
DOB: DATE OF REPORT:
PHYSICIAN: DATE OF PRINTING:
COPY TO:

Procedures/Addenda

Addendum

Date Ordered:

Status: Signed Out

Date Complete:

By:

Date Reported:

Addendum Diagnosis

Specimen A: This addendum is issued to clarify the status of the circumferential margin on the previously issued checklist. The adenocarcinoma is within 0.05 cm of the apparent serosal surface, not the circumferential margin. The remaining diagnosis remains unchanged.

Addendum Comment

{Not Entered}

Material Received:

A: tumor

History:

A -year-old female with a clinical history of right colon cancer.

Final Diagnosis:

- A. Right colonic segment, terminal ileal segment, appendix and pericolic lymph nodes (13), "tumor", right hemicolectomy:
Mucinous adenocarcinoma, signet ring cell type, extending extensively into subserosal tissue. See comment.
Pericolic lymph nodes: There is no evidence of malignancy (0/13).

Comment:

Colectomy
Specimen Type: Right hemicolectomy
Tumor Site: Cecum
Gross Configuration: Exophytic, Ulcerating
Tumor Size: 7.0 x 7.0 x 5.0 cm

MR #:

Page 1 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

CHIEF ICD-O-3
Adenocarcinoma, mucinous NOS 8480/3
path *Adenocarcinoma, mucinous, right sigmoid cell*
8480/3 *8490/3*
Code to highest 8490/3
Site: Cecum C18.0
7/25/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Histologic Type: Mucinous adenocarcinoma, signet ring cell type
Histologic Grade: Moderately to poorly
Pre-existing Polyp: Not identified
Surgical Margins: Negative for carcinoma
Proximal Margin: 4.5 cm from carcinoma
Distal Margin: 5.5 cm from carcinoma
Distance of invasive carcinoma from closest margin: Less than 0.05cm
Specify margin: Circumferential (Radial) margin
Depth of Invasion: Subserosal tissue
Perforation: No. Obstruction: Yes
Vascular Invasion: Not identified
Perineural Invasion: Not identified
Tumor Border Configuration: Pushing
Additional Pathologic Findings: Hyperplastic polyp
Lymph Nodes:
Number Examined: 13
Number Involved: 0
Prognostic Markers: See for addendum
: No (Sample was sent for analysis by instead)
Gross Picture Taken: No
Pathologic Staging (pTNM): pT3N0Mx

Primary Tumor (pT)

pT3: Tumor invades through the muscularis propria into the subserosa or the nonperitonealized pericolic or perirectal soft tissues

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Distant Metastasis (pM)

pMX: Cannot be assessed

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Immunostains for the following cytokeratins (pan-cytokeratin, CAM 5.2 and OSCAR) performed on selected lymph node sections are negative consistent with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh and subsequently placed in formalin labeled with the patient's name and "tumor", is a 14.0 cm colectomy specimen with a diameter of 4.5 cm and two stapled margins. The specimen is opened along the antimesenteric site to reveal a large friable fungating mass measuring 7.0 x 7.0 x 5.0 cm, filling the cecum. The mass is 5.5 cm from the distal resection margin and 4.5 cm from the proximal resection margin. The mass appears to be circumferential and due to the size of the mass, distorts the specimen. There is an attached appendix, 10.0 cm in length with an average diameter of 0.7 cm. The appendix is serially sectioned revealing a 0.2 cm lumen filled with brown soft fecal material. The appendix does not appear to be involved by the mass. The appendiceal orifice is inked green. The distal margin is marked by a suture and is inked blue. The pericolic fat deep to the mass is inked black. The mass is sectioned to reveal an average thickness of 0.9 cm. The mass appears to extend through the submucosal and into the wall. The mass focally replaces the wall and extends into the pericolic fat. The remainder of the mucosa is tan-pink with mucosal folds arranged in the usual manner, however, there is a 0.7 x 0.7 x 0.3 cm tan-pink polyp that is 1.0 cm from the blue inked distal resection margin. Sectioning of the pericolic fat reveals 13 possible lymph nodes ranging in size from 0.3 x 0.3 x 0.3 cm to 1.3 x 1.2 x 1.0 cm. The remainder of the pericolic fat is unremarkable.

MR #:

Page 2 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

A portion of the mass is submitted in cassettes A1FS for frozen and permanent section. The remainder of the specimen is submitted as follows:

- A2 - Small polyp 1.0 cm from the distal margin.
- A3 - Distal 1/3 of the appendix.
- A4 - Middle 1/3 of the appendix.
- A5 - Proximal 1/3 of the appendix, green ink indicates appendiceal orifice.
- A6 - Distal resection margin, parallel.
- A7 - Proximal resection margin, parallel.
- A8 through A11- Representative section of mass including deepest invasion.
- A12 - Unremarkable mucosa.
- A13 - One apparent lymph node, trisected and submitted in its entirety.
- A14 - One apparent lymph node, bisected in its entirety.
- A15 - One apparent lymph node, bisected in its entirety.
- A16 - One apparent lymph node, bisected in its entirety.
- A17 - Two apparent lymph nodes, each bisected and one is inked black and one is uninked.
- A18 - Two apparent lymph nodes, each bisected and one is uninked and one is inked black.
- A19 - Two apparent lymph nodes, each bisected and one is uninked and one is inked black.
- A20 - Two apparent lymph nodes, each bisected and one is inked black and one is uninked.
- A21 - One lymph node in its entirety.
- A22-A31 Additional sections from the tumor mass

Intraoperative Consultation:

A1FS, "tumor":

Adenocarcinoma with abundant mucin and necrosis. Sections sent for testing. The proximal and distal margins are grossly free of cancer.

If immunohistochemical stains and/or in situ hybridization are cited in this report, the performance characteristics were determined by the in compliance with CLIA'88 regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA. Known positive and negative control tissues demonstrate appropriate staining. This testing was developed by the It has not been cleared or approved by the FDA. The FDA has determined that such clearance or approval is not necessary.

Criteria	hw 2/18/14	Yes	No

MR #:

Page 3 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 365bb740-b236-403e-b514-d8d59f875787 (TCGA-WS-AB45.E9A99C0B-87F4-4E91-A80F-7F9AABB84CBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).